Somatic mutation profile of tumor specimen TCGA-CR-6472-01A (aliquot TCGA-CR-6472-01A-11D-1870-08) from TCGA case TCGA-CR-6472, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; Tumor grade: G3; Age at diagnosis: 59.3 years (21,654 days).
Specimen TCGA-CR-6472-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 068e7fe6-6207-47b7-afd6-5b381bd9b493.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-6472-10A (Blood Derived Normal), aliquot TCGA-CR-6472-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35f2c3e5-1874-488b-8367-df4d9859b14a

The open-access MAF lists 521 somatic variants for this specimen: 390 protein-altering or splice-affecting, 123 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 331, Silent 123, Nonsense Mutation 37, Frame Shift Del 9, Splice Site 5, Intron 3, In Frame Del 3, RNA 2, 3'Flank 2, Nonstop Mutation 2, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 51/100 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AAK1 | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as rs766166655, COSV68643542; called by muse, mutect2, varscan2
- ABCA3 | c.3832G>A p.E1278K | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.94); PolyPhen benign (0.009); catalogued as rs549548321, COSV100068099; called by muse, mutect2, varscan2
- ABI1 | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.017); catalogued as COSV61018424; called by muse, mutect2, varscan2
- AC013477.1 | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.688); catalogued as COSV99548725, COSV99549165; called by muse, mutect2, varscan2
- AC013477.1 | c.2467G>C p.E823Q | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV53654343, COSV99548749; called by mutect2, varscan2
- ACACB | c.4600G>C p.E1534Q | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.789); catalogued as COSV100622406; called by muse, mutect2, varscan2
- ACAD11 | c.1986G>C p.K662N | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV53895950, COSV53899098, COSV99391648; called by muse, mutect2, varscan2
- ACTN1 | c.1323G>C p.E441D | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.693); catalogued as COSV99517361; called by muse, mutect2, varscan2
- ADGRD1 | c.1592G>C p.R531T | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as COSV99894274; called by muse, mutect2, varscan2
- ADGRG4 | c.5128G>A p.D1710N | Missense Mutation (SNP) | VAF 87/113 reads (77%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV99794529; called by muse, mutect2, varscan2
- ADH1C | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 101/179 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV101565160; called by muse, mutect2, varscan2
- AFF4 | c.1954G>C p.D652H | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99534655; called by muse, mutect2, varscan2
- AGO4 | c.1369G>C p.D457H | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV100942788, COSV64617285; called by muse, mutect2, varscan2
- AHR | c.1782C>G p.F594L | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV99619355; called by muse, mutect2, varscan2
- ANKRD26 | c.2664G>C p.E888D | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV101062967; called by muse, mutect2, varscan2
- ANXA6 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.262); catalogued as rs370325414, COSV100637121; called by muse, mutect2, varscan2
- AP3M1 | c.173G>A p.S58N | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.02); catalogued as COSV100786662; called by muse, mutect2, varscan2
- APC | c.780G>C p.Q260H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV99965734; called by muse, mutect2, varscan2
- ARFGAP1 | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100796639; called by muse, mutect2, varscan2
- ARHGAP10 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.19); PolyPhen benign (0.324); catalogued as COSV100330943; called by muse, mutect2, varscan2
- ARHGAP17 | c.1496G>C p.G499A | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV99252955; called by muse, mutect2, varscan2
- ARHGAP6 | c.1168C>G p.Q390E | Missense Mutation (SNP) | VAF 96/130 reads (74%) | SIFT tolerated (0.96); PolyPhen benign (0.01); catalogued as COSV100272390; called by muse, mutect2, varscan2
- ARL1 | c.248C>G p.S83* | Nonsense Mutation (SNP) | VAF 30/117 reads (26%) | catalogued as COSV55370067; called by muse, mutect2, varscan2
- ARR3 | c.368C>G p.S123C | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100330803; called by muse, mutect2, varscan2
- ASPM | c.7501C>T p.Q2501* | Nonsense Mutation (SNP) | VAF 48/180 reads (27%) | catalogued as COSV54126997; called by muse, mutect2, varscan2
- ASXL3 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV52473245, COSV99323657; called by muse, mutect2, varscan2
- ATAD5 | c.2831G>C p.R944T | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV100429698; called by muse, mutect2, varscan2
- ATP6AP2 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as COSV101011417; called by muse, mutect2, varscan2
- BBS2 | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV99802133; called by muse, mutect2, varscan2
- BCHE | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs765480578, COSV100012174; called by muse, mutect2, varscan2
- BCL6 | c.782C>G p.P261R | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV99215423, COSV99216194; called by muse, mutect2, varscan2
- BCLAF1 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV100786410; called by muse, mutect2, varscan2
- BICDL1 | c.1373C>T p.S458F | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.563); catalogued as COSV99985757; called by muse, mutect2, varscan2
- C12orf50 | c.718C>T p.H240Y | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.439); catalogued as rs753291098, COSV53893854, COSV53894105; called by muse, mutect2, varscan2
- C12orf71 | c.229C>G p.Q77E | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV101460494; called by muse, mutect2, varscan2
- C1orf87 | c.48G>C p.E16D | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV100966947; called by muse, mutect2, varscan2
- C5 | c.178C>G p.P60A | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV99797262; called by muse, mutect2, varscan2
- C6orf120 | c.393G>A p.M131I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV100179069; called by muse, mutect2, varscan2
- CACNA1C | c.4519G>A p.E1507K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100215985; called by muse, mutect2, varscan2
- CACNA1E | c.1937C>G p.A646G | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100701364; called by muse, mutect2
- CACNB1 | c.841C>G p.L281V | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100703319; called by muse, mutect2, varscan2
- CARMIL1 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 19/35 reads (54%) | catalogued as COSV100277042, COSV61517774; called by muse, mutect2, varscan2
- CASZ1 | c.3387G>A p.M1129I | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV100680829; called by muse, mutect2, varscan2
- CBFA2T3 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs747418254, COSV99241181; called by muse, mutect2
- CCDC107 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100526185; called by muse, mutect2, varscan2
- CCDC18 | c.131C>G p.S44C | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV100159280; called by muse, mutect2, varscan2
- CCDC191 | c.1735G>C p.E579Q | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.163); catalogued as COSV99877956; called by muse, mutect2, varscan2
- CD46 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 115/481 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as COSV100522787; called by muse, mutect2, varscan2
- CDK18 | c.610G>C p.E204Q (on ENST00000506784 / NM_212503.3; = p.E174Q on NM_002596.4) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100773926; called by muse, mutect2, varscan2
- CELSR3 | c.1066G>C p.E356Q | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV50841296, COSV50842619; called by muse, mutect2, varscan2
- CEP350 | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100854347; called by muse, mutect2, varscan2
- CHCHD6 | c.284C>G p.A95G | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV52070049, COSV99335737; called by muse, mutect2, varscan2
- CHRNA4 | c.499T>G p.F167V | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV64718977; called by muse, mutect2, varscan2
- CMTM2 | c.506G>C p.R169T | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as COSV51749504; called by muse, mutect2, varscan2
- CNN2 | c.212C>G p.S71C | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99567588; called by muse, mutect2, varscan2
- CNOT10 | c.1393C>A p.L465I | Missense Mutation (SNP) | VAF 104/294 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV100094087, COSV59392671; called by muse, mutect2, varscan2
- COL13A1 | c.1611G>C p.E537D (on ENST00000398978 / NM_001130103.2; = p.E480D on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.982); catalogued as COSV100637321; called by muse, mutect2, varscan2
- COL24A1 | c.3967C>A p.P1323T | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100992964, COSV65302250; called by muse, mutect2, varscan2
- COL5A2 | c.1307C>G p.S436C | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as COSV100880040; called by muse, mutect2, varscan2
- COL5A3 | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99318302; called by muse, mutect2, varscan2
- COLGALT2 | c.787A>G p.T263A | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV100730428; called by muse, mutect2, varscan2
- COMMD5 | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100295678; called by muse, mutect2, varscan2
- COPA | c.209G>C p.G70A | Missense Mutation (SNP) | VAF 76/327 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99614802; called by muse, mutect2, varscan2
- COPG1 | c.1007C>G p.S336* | Nonsense Mutation (SNP) | VAF 35/83 reads (42%) | catalogued as COSV100135401; called by muse, mutect2, varscan2
- CORO1C | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1292307168, COSV54593770; called by muse, mutect2, varscan2
- CPEB3 | c.1384C>T p.R462C | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs767383587, COSV99798681; called by muse, mutect2, varscan2
- CRELD1 | c.784T>C p.C262R | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99926374; called by muse, mutect2, varscan2
- CXorf38 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); catalogued as COSV59947987; called by muse, mutect2, varscan2
- CYTH1 | c.636G>C p.E212D | Missense Mutation (SNP) | VAF 142/519 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100739177; called by muse, mutect2, varscan2
- DCAF6 | c.1802C>T p.S601L (on ENST00000312263 / NM_001349778.1; = p.S621L on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/214 reads (21%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV100393994; called by muse, mutect2, varscan2
- DCDC1 | c.2749C>A p.P917T (on ENST00000597505 / NM_001367979.1; = p.P24T on NM_020869.3) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV100337896; called by muse, mutect2, varscan2
- DDR2 | c.1885A>G p.M629V | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV63370696; called by muse, mutect2
- DDX54 | c.819G>T p.Q273H | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100013622; called by muse, mutect2, varscan2
- DEFB126 | c.138G>C p.K46N | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs182093028, COSV66694864; called by muse, mutect2, varscan2
- DLGAP4 | c.2978G>C p.*993Sext*10 (on ENST00000339266 / NM_001365621.1; = p.*990Sext*10 on NM_014902.6) | Nonstop Mutation (SNP) | VAF 23/51 reads (45%) | catalogued as COSV100210866; called by muse, mutect2, varscan2
- DNAH3 | c.11542C>G p.L3848V | Missense Mutation (SNP) | VAF 60/220 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54556688; called by muse, mutect2, varscan2
- DNTTIP1 | c.650C>G p.S217C | Missense Mutation (SNP) | VAF 104/270 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV101009986, COSV65460739; called by muse, mutect2, varscan2
- DOP1A | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1323001292, COSV52719624; called by muse, mutect2, varscan2
- DPP7 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT tolerated (0.89); PolyPhen benign (0.091); catalogued as rs748673481, COSV100857304; called by muse, mutect2, varscan2
- DPY19L1 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV100204491; called by muse, mutect2, varscan2
- DPY19L3 | c.1312C>T p.H438Y | Missense Mutation (SNP) | VAF 89/218 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV100639125; called by muse, mutect2, varscan2
- DUSP16 | c.1114G>C p.E372Q | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.265); catalogued as rs756649680, COSV53807332, COSV99962963; called by muse, mutect2, varscan2
- E2F7 | c.2365G>A p.G789R | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV100523338; called by muse, mutect2, varscan2
- ECI1 | c.189G>C p.K63N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs1483612333, COSV100066597; called by muse, mutect2, varscan2
- ECSIT | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs373495105; called by muse, mutect2, varscan2
- EFCAB5 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as COSV100299850; called by muse, mutect2, varscan2
- EIF3D | c.1089G>A p.W363* | Nonsense Mutation (SNP) | VAF 102/292 reads (35%) | catalogued as COSV99341382; called by muse, mutect2, varscan2
- EIF4E2 | c.24G>C p.L8F | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV99298972; called by muse, mutect2
- ELFN2 | c.1663C>G p.L555V | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101297483, COSV68743852; called by muse, mutect2, varscan2
- ELP3 | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.127); catalogued as COSV99833815; called by muse, mutect2, varscan2
- EMC2 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.831); catalogued as COSV99623909; called by muse, mutect2, varscan2
- ENPP3 | c.980C>G p.S327C | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100716768; called by muse, mutect2, varscan2
- EPCAM | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 10/16 reads (63%) | catalogued as rs747738988, COSV99764035; called by muse, varscan2
- EPHA1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 106/260 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99313562; called by muse, mutect2, varscan2
- EPHA6 | c.2854G>C p.D952H | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67568781; called by muse, mutect2, varscan2
- EPHB6 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as rs1045338681, COSV67420772; called by muse, mutect2, varscan2
- EPHX2 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100994485; called by muse, mutect2, varscan2
- ERO1B | c.515C>A p.S172Y | Missense Mutation (SNP) | VAF 62/214 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100523927; called by muse, mutect2, varscan2
- EXOSC5 | c.484G>C p.D162H | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV55370497, COSV55372247; called by muse, mutect2, varscan2
- FAM120B | c.404C>G p.S135* | Nonsense Mutation (SNP) | VAF 39/110 reads (35%) | catalogued as COSV99378772, COSV99379016; called by muse, mutect2, varscan2
- FAM170A | c.176C>G p.S59C | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100088780, COSV58926336; called by muse, mutect2, varscan2
- FBXL16 | c.791C>A p.S264* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100178768; called by muse, mutect2, varscan2
- FBXO31 | c.825C>G p.I275M | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV100291278; called by muse, mutect2, varscan2
- FCGR1A | c.988G>C p.D330H | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.31); catalogued as COSV100977264; called by muse, mutect2, varscan2
- FGD6 | c.1160A>T p.N387I | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.243); catalogued as COSV100676402; called by muse, mutect2
- FLG | c.5179G>A p.E1727K | Missense Mutation (SNP) | VAF 169/671 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs750879496, COSV64238023, COSV64244622; called by muse, mutect2, varscan2
- FLOT2 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.505); catalogued as COSV101204745; called by muse, mutect2, varscan2
- FNDC3B | c.3103G>A p.E1035K | Missense Mutation (SNP) | VAF 55/101 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as rs751522795, COSV100393692; called by muse, mutect2, varscan2
- FSCN3 | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs753723468, COSV56170122; called by muse, mutect2, varscan2
- GAB1 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 50/84 reads (60%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs761299664, COSV53761786; called by muse, mutect2, varscan2
- GABRA5 | c.1038G>C p.K346N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV100164800, COSV59482787; called by muse, mutect2, varscan2
- GAL | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV99681845; called by muse, mutect2, varscan2
- GBP2 | c.1113C>G p.F371L | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1297173140, COSV100975349, COSV65070343; called by muse, mutect2, varscan2
- GCM1 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.62); catalogued as rs1399106125, COSV99452152; called by muse, mutect2, varscan2
- GDI2 | c.1311G>C p.K437N | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV100050037; called by muse, mutect2, varscan2
- GEN1 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 76/105 reads (72%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.487); catalogued as COSV100437808; called by muse, mutect2, varscan2
- GJA8 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV99569138; called by muse, mutect2
- GLIPR2 | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1046499773, COSV100936994, COSV65029376; called by muse, mutect2, varscan2
- GPRC6A | c.116G>C p.G39A | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100114066; called by muse, mutect2, varscan2
- GRIK5 | c.1066G>C p.D356H | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as COSV99490094; called by muse, mutect2, varscan2
- GTF3C6 | c.430C>G p.L144V | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV100328673; called by muse, mutect2, varscan2
- H2AC20 | c.315G>T p.Q105H | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100479709, COSV58613151; called by muse, mutect2, varscan2
- H4C12 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | catalogued as COSV100694725, COSV100694774; called by muse, mutect2, varscan2
- HCAR3 | c.540C>G p.F180L | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100811492; called by muse, mutect2
- HEXIM2 | c.438C>A p.F146L | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100217862; called by muse, mutect2, varscan2
- HEY1 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.658); catalogued as rs781040574, COSV100559169; called by muse, varscan2
- HIF3A | c.19C>G p.R7G | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV52196448, COSV99355567; called by muse, mutect2, varscan2
- HIPK3 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV100305467; called by muse, mutect2, varscan2
- HIRIP3 | c.106C>A p.H36N | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV99662878, COSV99663040; called by muse, varscan2
- HOXC13 | c.909G>C p.Q303H | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99673291; called by muse, mutect2, varscan2
- HRC | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as COSV99417593; called by muse, varscan2
- HRC | c.588_589insCAG p.E196_E197insQ | In Frame Ins (INS) | VAF 24/72 reads (33%) | catalogued as COSV53255552; called by pindel, varscan2
- HUWE1 | c.1463G>A p.G488E | Missense Mutation (SNP) | VAF 48/68 reads (71%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99470835; called by muse, mutect2, varscan2
- IBTK | c.1370G>C p.G457A | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100090125; called by muse, mutect2, varscan2
- IFNGR2 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 15/31 reads (48%) | catalogued as COSV99274496; called by muse, mutect2, varscan2
- IHO1 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.275); catalogued as COSV99605858; called by muse, mutect2, varscan2
- IL16 | c.2770C>T p.P924S (on ENST00000302987 / NM_172217.5; = p.P223S on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.186); catalogued as COSV100267102; called by muse, mutect2, varscan2
- INHBE | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as rs571755879, COSV56989335; called by muse, mutect2, varscan2
- INPP5F | c.206G>C p.R69P | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100740002; called by muse, mutect2, varscan2
- INTS7 | c.984C>A p.F328L | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV100877408; called by muse, mutect2, varscan2
- INTS8 | c.1861C>T p.H621Y | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100569154; called by muse, mutect2, varscan2
- IRAK2 | c.1057C>T p.H353Y | Missense Mutation (SNP) | VAF 79/205 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1186848457, COSV99843768; called by muse, mutect2, varscan2
- IREB2 | c.2283C>G p.I761M | Missense Mutation (SNP) | VAF 94/260 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51921795, COSV51922389; called by muse, mutect2, varscan2
- ITGB4 | c.2318A>G p.H773R | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99563491; called by muse, mutect2, varscan2
- JAKMIP3 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1450633585, COSV100058729; called by muse, mutect2, varscan2
- JARID2 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 121/153 reads (79%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100521419, COSV100521752; called by muse, mutect2, varscan2
- JPH2 | c.122C>G p.S41C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100652517; called by muse, mutect2, varscan2
- KANSL1 | c.820C>G p.L274V | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs745792973, COSV52264909; called by muse, mutect2, varscan2
- KCNA2 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100315849; called by muse, mutect2, varscan2
- KCNH7 | c.2672G>A p.R891K | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100146992; called by muse, mutect2, varscan2
- KCNK5 | c.845G>A p.S282N | Missense Mutation (SNP) | VAF 81/132 reads (61%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100851747; called by muse, mutect2, varscan2
- KIR3DL3 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 124/461 reads (27%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.954); catalogued as COSV99399748; called by muse, mutect2, varscan2
- KRT38 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99878106; called by muse, mutect2, varscan2
- KY | c.1029G>C p.K343N | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.103); catalogued as rs1385394740, COSV101414951; called by muse, mutect2, varscan2
- LAMB4 | c.4486C>G p.P1496A | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99223029; called by muse, mutect2, varscan2
- LAMC2 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 62/360 reads (17%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.906); catalogued as COSV99917121; called by muse, mutect2, varscan2
- LCAT | c.836C>G p.S279C | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.797); catalogued as COSV99862863; called by muse, mutect2, varscan2
- LDLRAD2 | c.796G>C p.A266P | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.502); catalogued as COSV100760710; called by muse, mutect2, varscan2
- LEO1 | c.1798+2T>A p.X600_splice | Splice Site (SNP) | VAF 61/200 reads (31%) | catalogued as COSV100166413; called by muse, mutect2, varscan2
- LGR6 | c.2593G>A p.D865N (on ENST00000367278 / NM_001017403.1; = p.D813N on NM_021636.3) | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.191); catalogued as COSV99706228; called by muse, mutect2, varscan2
- LIN7B | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs767448567, COSV99674394; called by muse, mutect2, varscan2
- LITAF | c.408C>G p.F136L | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100243090; called by muse, mutect2, varscan2
- LRAT | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as CM126397, COSV100312029; called by muse, mutect2, varscan2
- LRRC8C | c.1552G>C p.E518Q | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100968086; called by muse, mutect2, varscan2
- LRRK2 | c.3521C>G p.S1174C | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV54168718; called by muse, mutect2, varscan2
- LTBP1 | c.2617G>T p.E873* (on ENST00000404816 / NM_206943.4; = p.E547* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 34/108 reads (31%) | catalogued as COSV100616483, COSV63196455; called by muse, mutect2, varscan2
- LTN1 | c.154C>G p.Q52E | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as COSV100797890; called by muse, mutect2, varscan2
- MACF1 | c.14446G>A p.D4816N (on ENST00000372915; = p.D2749N on NM_012090.5) | Missense Mutation (SNP) | VAF 112/292 reads (38%) | catalogued as COSV99241740; called by muse, mutect2, varscan2
- MACF1 | c.18616G>A p.E6206K (on ENST00000372915; = p.E4251K on NM_012090.5) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | catalogued as COSV99241741, COSV99242240; called by muse, mutect2
- MAP11 | c.843C>T p.V281= | Splice Region (SNP) | VAF 25/94 reads (27%) | catalogued as COSV100385371; called by muse, mutect2, varscan2
- MAP11 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57587204; called by muse, mutect2, varscan2
- MAP3K12 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV99912999; called by muse, mutect2, varscan2
- MARK1 | c.1321C>G p.Q441E | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as COSV100857077; called by muse, varscan2
- MCM4 | c.2016G>C p.Q672H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.489); catalogued as COSV50631859; called by muse, mutect2, varscan2
- MED11 | c.254C>G p.S85C | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.213); catalogued as rs1567693668, COSV99543414; called by muse, mutect2, varscan2
- METTL1 | c.528C>G p.I176M | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99141519; called by muse, mutect2, varscan2
- MIA3 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as COSV100719331; called by muse, mutect2, varscan2
- MPPED1 | c.315C>G p.I105M | Missense Mutation (SNP) | VAF 58/99 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.215); catalogued as COSV100501148; called by muse, mutect2, varscan2
- MRPS35 | c.256C>G p.R86G | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs769806923, COSV99317316; called by muse, mutect2, varscan2
- MSRA | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV100412451; called by muse, mutect2, varscan2
- MST1R | c.3352C>T p.R1118C | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs755404861, COSV56569479; called by muse, mutect2, varscan2
- MTA2 | c.351G>C p.L117F | Missense Mutation (SNP) | VAF 194/581 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV99604047; called by muse, varscan2
- MUC16 | c.21370C>T p.L7124F | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.001); catalogued as rs201097594, COSV101200286; called by muse, mutect2, varscan2
- MYH10 | c.5881G>C p.E1961Q | Missense Mutation (SNP) | VAF 98/166 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as COSV52607540; called by muse, mutect2, varscan2
- MYH10 | c.4632G>C p.M1544I | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as COSV99344274; called by muse, mutect2, varscan2
- MYH11 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 28/83 reads (34%) | catalogued as COSV100257877; called by muse, mutect2, varscan2
- MYH7 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 54/90 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs773740053, COSV62525007; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO9A | c.6040G>A p.E2014K | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV100612764; called by muse, varscan2
- MYOG | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.492); catalogued as rs1023300069, COSV99613852; called by muse, mutect2, varscan2
- MYT1 | c.308C>G p.S103C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV100114064; called by muse, mutect2, varscan2
- N4BP1 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.086); catalogued as COSV99284811; called by muse, mutect2, varscan2
- N4BP1 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 28/71 reads (39%) | catalogued as COSV99284819; called by muse, mutect2, varscan2
- NAF1 | c.1465C>T p.H489Y | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV99918926; called by muse, mutect2, varscan2
- NAGS | c.1152C>G p.D384E | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.04); catalogued as COSV99243712; called by muse, mutect2, varscan2
- NDNF | c.1195C>T p.Q399* | Nonsense Mutation (SNP) | VAF 49/94 reads (52%) | catalogued as COSV101113097; called by muse, mutect2, varscan2
- NEK1 | c.1777G>C p.E593Q | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV101455626; called by muse, mutect2, varscan2
- NEK10 | c.2126A>C p.K709T | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99834826; called by muse, mutect2, varscan2
- NELL1 | c.1877C>T p.S626F | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (0.24); PolyPhen benign (0.073); catalogued as COSV100119373; called by muse, mutect2, varscan2
- NFATC3 | c.1975C>G p.H659D | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as COSV100284926; called by muse, mutect2, varscan2
- NPHP3 | c.1507G>C p.E503Q | Missense Mutation (SNP) | VAF 98/209 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV100446639; called by muse, mutect2, varscan2
- NR1D2 | c.41C>G p.S14C | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100437305; called by muse, mutect2, varscan2
- NR5A2 | c.1411G>C p.E471Q (on ENST00000367362 / NM_205860.3; = p.E425Q on NM_003822.5) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.164); catalogued as COSV52656462, COSV99370732; called by muse, mutect2
- NRDC | c.3178G>A p.D1060N | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as COSV61403626; called by muse, mutect2, varscan2
- NSL1 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs1208906222, COSV100875187; called by muse, mutect2, varscan2
- NUGGC | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV100428987; called by muse, mutect2, varscan2
- NUP205 | c.3179C>G p.A1060G | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.619); catalogued as COSV99606545; called by muse, mutect2, varscan2
- NUP43 | c.829C>G p.L277V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100461931; called by muse, mutect2, varscan2
- NUTM1 | c.1122C>G p.I374M | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100148853, COSV59218700; called by muse, mutect2, varscan2
- ONECUT2 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs975677902, COSV101529756; called by muse, mutect2, varscan2
- OR2A2 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101286621; called by muse, mutect2, varscan2
- OR2G2 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 59/227 reads (26%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.971); catalogued as COSV100189608; called by muse, mutect2, varscan2
- OR8I2 | c.149G>A p.R50K | Missense Mutation (SNP) | VAF 102/274 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV100135876, COSV100136287, COSV56170158; called by muse, mutect2, varscan2
- OR8S1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs1565580265, COSV100043469; called by muse, varscan2
- P2RY13 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV56396463; called by muse, mutect2, varscan2
- PABPC1L | c.1687G>A p.D563N | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs368203711; called by muse, mutect2, varscan2
- PANX2 | c.1050C>G p.F350L | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV99348019; called by muse, mutect2, varscan2
- PCDHB6 | c.2270C>G p.S757* | Nonsense Mutation (SNP) | VAF 72/179 reads (40%) | catalogued as COSV99169942; called by muse, mutect2, varscan2
- PCDHGA1 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV65299544; called by muse, mutect2, varscan2
- PCDHGA1 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 55/199 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.16); catalogued as rs563853936, COSV65295089, COSV65298925; called by muse, mutect2, varscan2
- PCDHGA12 | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.826); catalogued as rs939325676, COSV52744266; called by muse, mutect2, varscan2
- PCDHGA9 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 63/161 reads (39%) | catalogued as COSV54006375, COSV54058343, COSV99532223; called by muse, mutect2, varscan2
- PDCD2L | c.781C>G p.Q261E | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.448); catalogued as COSV99874880; called by muse, mutect2, varscan2
- PDE8B | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.86); PolyPhen benign (0.062); catalogued as COSV99366240; called by muse, mutect2, varscan2
- PDIA2 | c.1283G>C p.W428S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99249379; called by muse, mutect2, varscan2
- PDZRN3 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 84/227 reads (37%) | SIFT tolerated (0.96); PolyPhen benign (0.101); catalogued as COSV99727773; called by muse, mutect2, varscan2
- PEX1 | c.2330G>C p.G777A | Missense Mutation (SNP) | VAF 132/353 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV99951913; called by muse, mutect2, varscan2
- PGLYRP2 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV99483797; called by muse, mutect2, varscan2
- PHF20L1 | c.2694G>A p.M898I | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99620499; called by muse, mutect2, varscan2
- PHLPP1 | c.3826G>C p.D1276H | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV99407493; called by muse, mutect2, varscan2
- PHOX2A | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV53359364; called by muse, mutect2, varscan2
- PIK3C2G | c.689G>C p.C230S | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.167); catalogued as COSV99849926; called by muse, mutect2
- PIK3CD | c.786C>G p.I262M | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV100740003; called by muse, mutect2, varscan2
- PJA2 | c.1672G>A p.D558N | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100754316; called by muse, mutect2, varscan2
- PKD1 | c.8212G>C p.E2738Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as COSV51927949, COSV99237285; called by muse, mutect2, varscan2
- PLCB2 | c.715G>C p.E239Q | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV99541631; called by muse, mutect2, varscan2
- PLEKHA3 | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 66/99 reads (67%) | catalogued as rs368349837; called by muse, mutect2, varscan2
- PLEKHG1 | c.1951G>C p.E651Q | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.937); catalogued as COSV100651482; called by muse, mutect2, varscan2
- PLEKHG2 | c.3664G>C p.D1222H | Missense Mutation (SNP) | VAF 92/273 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV99216944; called by muse, mutect2, varscan2
- PLS1 | c.365-1G>C p.X122_splice | Splice Site (SNP) | VAF 21/72 reads (29%) | catalogued as COSV100537972; called by muse, mutect2, varscan2
- PLXNB1 | c.5811C>G p.F1937L | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99602358; called by muse, mutect2, varscan2
- PNISR | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV100984312, COSV65080483; called by muse, mutect2, varscan2
- POLQ | c.527C>G p.S176C | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV99951723; called by muse, mutect2, varscan2
- POLR3F | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.18); catalogued as COSV99361924; called by muse, mutect2, varscan2
- POLRMT | c.3027G>T p.Q1009H | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99241344; called by muse, mutect2, varscan2
- PPP1R2 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 64/120 reads (53%) | catalogued as COSV100113297, COSV100113367; called by muse, mutect2, varscan2
- PPP1R21 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 67/100 reads (67%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs376485954; called by muse, mutect2, varscan2
- PRKACA | c.1039G>C p.E347Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV99513731; called by muse, mutect2
- PRKAR1A | c.761C>G p.S254C | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs1555814475, CD002528, COSV100675099; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKDC | c.3733C>T p.R1245W | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs200017529; called by muse, mutect2, varscan2
- PRKRIP1 | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 70/182 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV100700316; called by muse, mutect2, varscan2
- PROS1 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM991068, COSV100820210; called by muse, mutect2, varscan2
- PRPF40A | c.240G>A p.M80I | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.584); catalogued as COSV58442711; called by muse, mutect2, varscan2
- PRR27 | c.469G>C p.E157Q | Missense Mutation (SNP) | VAF 45/57 reads (79%) | SIFT tolerated (0.28); PolyPhen benign (0.127); catalogued as COSV60640583; called by muse, mutect2, varscan2
- PRRC2C | c.6106C>G p.P2036A (on ENST00000367742; = p.P2034A on NM_015172.4) | Missense Mutation (SNP) | VAF 104/402 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100144754; called by muse, mutect2, varscan2
- PRRC2C | c.8446G>T p.E2816* (on ENST00000367742; = p.E2814* on NM_015172.4) | Nonsense Mutation (SNP) | VAF 43/216 reads (20%) | catalogued as COSV100144755; called by muse, mutect2, varscan2
- PRSS27 | c.397C>G p.P133A | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.103); catalogued as COSV100234474; called by muse, varscan2
- PSCA | c.248G>A p.C83Y | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100008188; called by muse, mutect2, varscan2
- PUS3 | c.712C>G p.Q238E | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT tolerated (0.33); PolyPhen benign (0.065); catalogued as COSV57102711; called by muse, mutect2, varscan2
- PVR | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.716); catalogued as COSV51823646; called by muse, mutect2, varscan2
- QSER1 | c.756G>C p.K252N (on ENST00000399302; = p.K381N on NM_001076786.3) | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV101234678; called by muse, mutect2, varscan2
- RABGAP1L | c.1608G>C p.K536N | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV99268231; called by muse, mutect2, varscan2
- RADIL | c.1527G>A p.W509* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as rs768081806, COSV101271281; called by muse, mutect2, varscan2
- RALGAPA2 | c.1340G>C p.R447T | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99173190; called by muse, mutect2, varscan2
- RAPGEFL1 | c.1372G>A p.G458S | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.52); PolyPhen benign (0.021); catalogued as rs890742600, COSV99228711; called by muse, mutect2, varscan2
- RASAL2 | c.129C>G p.F43L | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100862442; called by muse, mutect2, varscan2
- RELCH | c.1273G>A p.V425I | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99901518; called by muse, mutect2, varscan2
- RELT | c.170C>G p.S57* | Nonsense Mutation (SNP) | VAF 24/89 reads (27%) | catalogued as COSV99292688; called by muse, mutect2, varscan2
- RET | c.2836A>G p.T946A | Missense Mutation (SNP) | VAF 77/191 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV100392607; called by muse, mutect2, varscan2
- RETREG3 | c.1338C>G p.D446E | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99518758; called by muse, mutect2, varscan2
- RETREG3 | c.1159C>T p.L387F | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as COSV53817220; called by muse, mutect2, varscan2
- RGL4 | c.374-1G>A p.X125_splice | Splice Site (SNP) | VAF 23/62 reads (37%) | catalogued as COSV51945199, COSV99318645; called by muse, mutect2, varscan2
- RNASEL | c.565G>C p.D189H | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.04); catalogued as COSV100842550; called by muse, mutect2, varscan2
- RNF111 | c.2164C>T p.Q722* | Nonsense Mutation (SNP) | VAF 53/157 reads (34%) | catalogued as COSV62087631; called by muse, mutect2, varscan2
- RNF213 | c.12991G>A p.G4331S | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs781405923, COSV60396431; called by muse, mutect2, varscan2
- ROBO1 | c.1111C>A p.Q371K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.932); catalogued as COSV101458337; called by muse, mutect2, varscan2
- RORA | c.1100G>A p.R367K (on ENST00000335670 / NM_134261.3; = p.R392K on NM_002943.3) | Missense Mutation (SNP) | VAF 110/303 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV55035093, COSV99832232; called by muse, mutect2, varscan2
- RPL3L | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs773393186, COSV51907714; called by muse, mutect2, varscan2
- RRP12 | c.3610G>A p.E1204K | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs116818150; called by muse, mutect2, varscan2
- RSPRY1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 89/227 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101070938, COSV68027348; called by muse, mutect2, varscan2
- RTN3 | c.1877C>A p.S626* (on ENST00000377819 / NM_001265589.2; = p.S607* on NM_201428.3) | Nonsense Mutation (SNP) | VAF 43/110 reads (39%) | catalogued as COSV58029289; called by muse, mutect2, varscan2
- RYR1 | c.5122G>A p.A1708T | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.18); catalogued as rs376833141, COSV100614740; called by muse, mutect2, varscan2
- SALL1 | c.1513C>G p.H505D | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99171632; called by muse, mutect2, varscan2
- SBK2 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs553624707, COSV100705139, COSV60014020; called by muse, mutect2, varscan2
- SCN8A | c.2506G>C p.D836H | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV100633366; called by muse, mutect2, varscan2
- SCRIB | c.3700G>C p.E1234Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100252685; called by muse, mutect2, varscan2
- SDHAF2 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100073884; called by muse, mutect2, varscan2
- SDK2 | c.2157G>C p.Q719H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as COSV66180557, COSV66195393; called by muse, mutect2, varscan2
- SEC24C | c.1453G>T p.E485* | Nonsense Mutation (SNP) | VAF 80/224 reads (36%) | catalogued as COSV100226568; called by muse, mutect2, varscan2
- SELENOH | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99559792; called by muse, varscan2
- SERPINA10 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | catalogued as COSV100003651; called by muse, mutect2, varscan2
- SGCE | c.1082C>A p.S361* (on ENST00000647096; = p.S325* on NM_003919.3) | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as rs559353446, CD032135, COSV56017126, COSV56018835, COSV99722218; called by muse, mutect2, varscan2
- SGTA | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 69/234 reads (29%) | catalogued as COSV99682478; called by muse, mutect2, varscan2
- SHPRH | c.1918G>A p.D640N | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.035); catalogued as rs1396641725, COSV51609257; called by muse, mutect2, varscan2
- SLC22A16 | c.246G>C p.Q82H | Missense Mutation (SNP) | VAF 68/203 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100397211; called by muse, mutect2, varscan2
- SLC27A1 | c.1003C>G p.Q335E | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV99393026; called by muse, mutect2, varscan2
- SLC35D3 | c.1250G>C p.*417Sext*17 | Nonstop Mutation (SNP) | VAF 26/63 reads (41%) | catalogued as COSV100090356; called by muse, mutect2, varscan2
- SLC8A2 | c.731G>T p.W244L | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as COSV99369697; called by muse, mutect2, varscan2
- SMCHD1 | c.1493G>C p.R498T | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.644); catalogued as COSV99860784; called by muse, mutect2, varscan2
- SMCHD1 | c.2687C>A p.S896Y | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.642); catalogued as COSV99860787; called by muse, mutect2, varscan2
- SNF8 | c.42G>C p.K14N | Missense Mutation (SNP) | VAF 92/234 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as COSV99287723; called by muse, mutect2, varscan2
- SNX27 | c.581C>G p.S194C | Missense Mutation (SNP) | VAF 67/350 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV100918977; called by muse, mutect2, varscan2
- SOS1 | c.1051C>G p.L351V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.072); catalogued as rs771185305, COSV101216619; called by muse, mutect2
- SPAG9 | c.3446C>G p.T1149R (on ENST00000262013 / NM_001130528.3; = p.T1135R on NM_003971.6) | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100004598; called by muse, mutect2, varscan2
- SPTBN4 | c.435C>G p.I145M | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100150148, COSV58948616; called by muse, mutect2, varscan2
- SPTLC2 | c.1555G>C p.E519Q | Missense Mutation (SNP) | VAF 52/70 reads (74%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.461); catalogued as COSV53640569, COSV99377264; called by muse, mutect2, varscan2
- SRSF6 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV99719636; called by muse, mutect2, varscan2
- STAT2 | c.1642C>A p.P548T | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100028638; called by muse, mutect2, varscan2
- STOX1 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100057607; called by muse, mutect2, varscan2
- STX5 | c.983C>A p.S328Y | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99585802; called by muse, mutect2, varscan2
- STYXL1 | c.737C>A p.S246Y | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1554566962, COSV99951262; called by muse, mutect2
- SV2A | c.1686C>G p.F562L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.229); catalogued as COSV100975027; called by muse, mutect2, varscan2
- SYNJ2BP | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99832593; called by muse, mutect2, varscan2
- SZT2 | c.6395C>T p.S2132L (on ENST00000634258 / NM_001365999.1; = p.S2075L on NM_015284.4) | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs747764184, COSV65175399; called by muse, mutect2, varscan2
- TAF1L | c.5323G>T p.D1775Y | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99644198; called by muse, mutect2, varscan2
- TAF5 | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV100674599; called by muse, mutect2, varscan2
- TAP1 | c.1966C>T p.Q656* | Nonsense Mutation (SNP) | VAF 27/45 reads (60%) | catalogued as COSV100841101; called by muse, mutect2, varscan2
- TARBP1 | c.3755C>G p.S1252* | Nonsense Mutation (SNP) | VAF 12/122 reads (10%) | catalogued as COSV99241151; called by muse, mutect2
- TBC1D10C | c.1284C>G p.I428M | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100408133, COSV56702256; called by muse, varscan2
- TBC1D10C | c.1319C>G p.S440C | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV100408136, COSV56702313; called by muse, varscan2
- TCIM | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.073); catalogued as rs10353, COSV100249561; called by muse, mutect2, varscan2
- TECR | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.2); catalogued as COSV99295022; called by muse, mutect2, varscan2
- TEX2 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs780968826, COSV51985860; called by muse, mutect2, varscan2
- TEX55 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | catalogued as COSV99817339, COSV99817672; called by muse, mutect2, varscan2
- TIAM1 | c.3539C>T p.S1180F | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as COSV99732493, COSV99732686, COSV99736194; called by muse, mutect2, varscan2
- TIAM1 | c.2054C>T p.S685F | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV99733162; called by muse, varscan2
- TNFRSF13C | c.325C>A p.R109S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.81); PolyPhen benign (0.031); catalogued as rs776189874, COSV52169225, COSV99351674, COSV99351810; called by muse, mutect2, varscan2
- TNFRSF19 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV99947145; called by muse, mutect2, varscan2
- TOPORS | c.2753C>T p.S918F | Missense Mutation (SNP) | VAF 73/123 reads (59%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV100859462, COSV62116479; called by muse, mutect2, varscan2
- TP53INP2 | c.181C>G p.P61A | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.055); catalogued as COSV100873673; called by muse, mutect2
- TRDN | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.419); catalogued as COSV100521003; called by muse, mutect2, varscan2
- TRIP11 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV99970383; called by muse, mutect2, varscan2
- TRIP12 | c.4999A>G p.T1667A | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV99389490; called by muse, mutect2, varscan2
- TSEN2 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as rs934468486, COSV99538857; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1954C>G p.R652G | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs375957094, COSV99534877; called by muse, mutect2, varscan2
- TSPYL1 | c.1060C>G p.P354A | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV100889564; called by muse, mutect2, varscan2
- TTC39C | c.1381C>G p.P461A (on ENST00000317571 / NM_001135993.2; = p.P400A on NM_153211.4) | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV100455199; called by muse, mutect2, varscan2
- TTLL6 | c.1817G>C p.R606T (on ENST00000393382 / NM_001130918.3; = p.R299T on NM_173623.3) | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.127); catalogued as COSV100938057; called by muse, mutect2, varscan2
- TTN | c.85880C>T p.S28627L (on ENST00000591111; = p.S21203L on NM_003319.4) | Missense Mutation (SNP) | VAF 71/116 reads (61%) | PolyPhen probably damaging (0.996); catalogued as COSV100597287; called by muse, mutect2, varscan2
- TXNDC11 | c.2518G>A p.E840K (on ENST00000356957 / NM_001303447.2; = p.E813K on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV99297344; called by muse, mutect2, varscan2
- UBA5 | c.1084C>G p.P362A | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV53905334, COSV99393121; called by muse, mutect2, varscan2
- UBASH3A | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs986395026, COSV99369299; called by muse, mutect2, varscan2
- UBE3A | c.2207G>A p.G736D | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99216825; called by muse, mutect2, varscan2
- UMODL1 | c.653C>G p.S218* | Nonsense Mutation (SNP) | VAF 23/31 reads (74%) | catalogued as rs1169601601, COSV101248427, COSV101248854; called by muse, mutect2, varscan2
- UPF1 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.276); catalogued as COSV99438906; called by muse, mutect2, varscan2
- UPF1 | c.1978C>A p.P660T (on ENST00000599848 / NM_001297549.2; = p.P649T on NM_002911.4) | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99438911; called by muse, mutect2, varscan2
- USP19 | c.1547C>G p.S516C | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100025877; called by muse, mutect2, varscan2
- USP19 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 71/118 reads (60%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100025878; called by muse, mutect2, varscan2
- USP33 | c.418C>G p.H140D | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.017); catalogued as COSV100657029; called by muse, mutect2, varscan2
- USP47 | c.667G>A p.E223K (on ENST00000399455 / NM_001372095.1; = p.E135K on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV60467387; called by muse, mutect2, varscan2
- VKORC1L1 | c.414C>G p.F138L | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs772176427, COSV100663099, COSV62488737; called by muse, mutect2, varscan2
- VPS53 | c.1595T>A p.L532H (on ENST00000571805 / NM_001366253.2; = p.L503H on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99345467; called by muse, mutect2
- WASF2 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs151177492; called by muse, mutect2, varscan2
- WNT2 | c.943A>C p.T315P | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99625765; called by muse, mutect2, varscan2
- WSB2 | c.715C>G p.Q239E | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as rs776589314, COSV99969774; called by muse, mutect2, varscan2
- XPNPEP3 | c.17C>A p.S6* | Nonsense Mutation (SNP) | VAF 9/14 reads (64%) | catalogued as COSV53421499, COSV99344003; called by muse, mutect2, varscan2
- XPR1 | c.1798G>C p.E600Q | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100851427, COSV100851504, COSV62555794; called by muse, mutect2, varscan2
- ZBP1 | c.503-1G>C p.X168_splice | Splice Site (SNP) | VAF 56/134 reads (42%) | catalogued as COSV100473501, COSV59064869; called by muse, mutect2, varscan2
- ZBTB16 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV60088768; called by muse, mutect2, varscan2
- ZBTB16 | c.1807G>C p.E603Q | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV100251059; called by muse, mutect2, varscan2
- ZNF169 | c.368C>A p.S123* | Nonsense Mutation (SNP) | VAF 29/52 reads (56%) | catalogued as COSV100566152, COSV61762990; called by muse, mutect2, varscan2
- ZNF211 | c.1262G>C p.G421A (on ENST00000347302 / NM_198855.4; = p.G434A on NM_006385.5) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99560093; called by muse, mutect2, varscan2
- ZNF214 | c.625C>G p.L209V | Missense Mutation (SNP) | VAF 41/64 reads (64%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.76); catalogued as COSV99547218; called by muse, mutect2, varscan2
- ZNF217 | c.511C>T p.L171F | Missense Mutation (SNP) | VAF 69/206 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100184243; called by muse, mutect2, varscan2
- ZNF3 | c.10C>G p.Q4E | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); catalogued as COSV99447121; called by muse, mutect2, varscan2
- ZNF407 | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs550259189, COSV55265167; called by muse, mutect2, varscan2
- ZNF432 | c.1696G>C p.E566Q | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV55417789, COSV99659106; called by muse, mutect2, varscan2
- ZNF462 | c.1568C>G p.S523* | Nonsense Mutation (SNP) | VAF 20/41 reads (49%) | catalogued as COSV99470920; called by muse, mutect2, varscan2
- ZNF473 | c.17T>G p.V6G | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV99568530, COSV99568543; called by muse, mutect2, varscan2
- ZNF547 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99987764; called by muse, mutect2, varscan2
- ZNF555 | c.142C>G p.Q48E | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100514539; called by muse, mutect2, varscan2
- ZNF69 | c.23G>T p.R8M | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.047); catalogued as COSV100420896; called by muse, mutect2, varscan2
- ZNF700 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs780610204, COSV99583310; called by muse, mutect2, varscan2
- ZNF99 | c.2158C>G p.L720V | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV101233725; called by muse, mutect2, varscan2
- ZNF99 | c.78G>T p.Q26H | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV101233726, COSV68054830, COSV68055694; called by muse, mutect2, varscan2
- ACTL6B | c.637_642del p.D213_I214del | In Frame Del (DEL) | VAF 11/22 reads (50%) | called by mutect2, pindel, varscan2
- ANKRD6 | c.959_969del p.A320Vfs*13 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | called by mutect2, varscan2
- ARHGEF1 | c.1611_1620del p.A538Rfs*14 | Frame Shift Del (DEL) | VAF 21/55 reads (38%) | called by mutect2, pindel, varscan2
- CELSR2 | c.6622_6623del p.V2208Lfs*36 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- E2F8 | c.1973_1982del p.E658Vfs*20 | Frame Shift Del (DEL) | VAF 58/113 reads (51%) | called by mutect2, pindel, varscan2
- HIVEP3 | c.6439_6452del p.P2147Sfs*12 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | called by mutect2, varscan2
- ITGAE | c.1288del p.A430Rfs*14 | Frame Shift Del (DEL) | VAF 4/8 reads (50%) | called by mutect2, varscan2
- KMT2E | c.385_398del p.D129Lfs*3 | Frame Shift Del (DEL) | VAF 26/97 reads (27%) | called by mutect2, varscan2
- MUC5B | c.9965C>G p.S3322C | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); called by muse, mutect2
- NACC1 | c.1121-13_1142delinsACCAACGTGTACATCACAA p.X374_splice | Splice Site (DEL) | VAF 19/130 reads (15%) | called by pindel, varscan2*
- OR11H1 | c.781_786del p.V261_M262del | In Frame Del (DEL) | VAF 43/304 reads (14%) | called by mutect2, pindel, varscan2
- OR11H12 | c.814_819del p.V272_M273del | In Frame Del (DEL) | VAF 45/191 reads (24%) | called by mutect2, pindel, varscan2
- SIPA1L2 | c.1243_1245delinsT p.E415Yfs*66 | Frame Shift Del (DEL) | VAF 56/278 reads (20%) | called by pindel, varscan2*
- SLC4A4 | c.3123dup p.V1042Sfs*5 (on ENST00000264485 / NM_001098484.3; = p.V998Sfs*5 on NM_003759.4) | Frame Shift Ins (INS) | VAF 58/222 reads (26%) | called by mutect2, pindel, varscan2
- TMEM132B | c.62_77del p.S21Ifs*71 | Frame Shift Del (DEL) | VAF 38/144 reads (26%) | called by mutect2, pindel, varscan2
- ABHD3 | c.846C>T p.H282= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100004225; called by muse, mutect2, varscan2
- ACHE | c.1710G>A p.L570= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99573785; called by muse, varscan2
- ADAM21 | c.1674C>G p.V558= | Silent (SNP) | VAF 39/72 reads (54%) | catalogued as COSV99960586; called by muse, mutect2, varscan2
- ADAMTS16 | c.870G>C p.L290= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as COSV99940257; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2964G>A p.P988= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs768211626, COSV65888740; called by muse, mutect2, varscan2
- ADCY7 | c.387C>T p.F129= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV54267378; called by muse, mutect2, varscan2
- ALPK3 | c.1974G>A p.Q658= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV99360294; called by muse, mutect2, varscan2
- ALPL | c.1206G>A p.L402= | Silent (SNP) | VAF 51/123 reads (41%) | catalogued as COSV100876170; called by muse, mutect2, varscan2
- AP2A1 | c.405C>T p.I135= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs547369327, COSV100756147; called by muse, mutect2, varscan2
- ARTN | c.489C>T p.L163= (on ENST00000372354; = p.L171= on NM_057090.2) | Silent (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2, varscan2
- ASPSCR1 | c.555G>C p.L185= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100144734; called by muse, mutect2, varscan2
- ASTN1 | c.1503C>T p.N501= | Silent (SNP) | VAF 196/671 reads (29%) | catalogued as rs375640704; called by muse, mutect2, varscan2
- ATG2A | c.5733G>C p.L1911= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV100815510; called by muse, mutect2, varscan2
- ATG2B | c.3198C>T p.F1066= | Silent (SNP) | VAF 39/75 reads (52%) | catalogued as COSV100737752; called by muse, varscan2
- ATP2C2 | c.447C>T p.F149= | Silent (SNP) | VAF 53/97 reads (55%) | catalogued as rs1247383730, COSV99297528; called by muse, mutect2, varscan2
- ATRN | c.1911C>T p.L637= | Silent (SNP) | VAF 43/172 reads (25%) | catalogued as COSV99496697; called by muse, mutect2, varscan2
- BASP1 | c.111G>A p.P37= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs767716479, COSV59470349; called by muse, mutect2, varscan2
- C12orf54 | c.339G>A p.L113= | Silent (SNP) | VAF 52/152 reads (34%) | catalogued as COSV100011517; called by muse, mutect2
- CATIP | c.657G>A p.Q219= | Silent (SNP) | VAF 25/37 reads (68%) | catalogued as COSV99179492; called by muse, mutect2, varscan2
- CCDC113 | c.840G>T p.L280= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as COSV99540707, COSV99540975; called by muse, mutect2, varscan2
- CD27 | c.45G>A p.L15= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV99869836; called by muse, mutect2, varscan2
- CDAN1 | c.2691C>G p.L897= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV100661185, COSV100661419; called by muse, mutect2, varscan2
- CDC42BPG | c.1392G>C p.L464= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV100711978; called by muse, mutect2, varscan2
- CDC42EP4 | c.672C>T p.I224= | Silent (SNP) | VAF 29/109 reads (27%) | catalogued as COSV100231756; called by muse, mutect2, varscan2
- CDH26 | c.1935G>A p.K645= | Silent (SNP) | VAF 78/213 reads (37%) | catalogued as rs1298318723, COSV99721884; called by muse, mutect2, varscan2
- CES4A | c.1614C>G p.L538= (on ENST00000648724 / NM_001364782.1; = p.L440= on NM_001190201.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 69/215 reads (32%) | catalogued as COSV100109980; called by muse, mutect2, varscan2
- CNGB1 | c.1722C>G p.L574= | Silent (SNP) | VAF 43/82 reads (52%) | catalogued as COSV99201677; called by muse, mutect2, varscan2
- COBL | c.2211G>T p.G737= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV99471501; called by muse, mutect2, varscan2
- COL6A6 | c.3375G>A p.L1125= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV100649905, COSV62034296; called by muse, mutect2, varscan2
- CPT1A | c.1542C>T p.Y514= | Silent (SNP) | VAF 51/129 reads (40%) | catalogued as COSV99680668; called by muse, mutect2, varscan2
- CREBBP | c.6000G>A p.L2000= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV99268789; called by muse, mutect2, varscan2
- CTSB | c.333C>T p.F111= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs762162520, COSV61540297; called by muse, mutect2, varscan2
- DDX20 | c.2238G>A p.L746= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as rs781063242, COSV100861988; called by muse, mutect2, varscan2
- DERL1 | c.222C>G p.V74= | Silent (SNP) | VAF 36/117 reads (31%) | catalogued as COSV99418291; called by muse, mutect2, varscan2
- DHTKD1 | c.2271C>T p.F757= | Silent (SNP) | VAF 45/138 reads (33%) | catalogued as rs1199087767, COSV99536096; called by muse, mutect2, varscan2
- DLGAP5 | c.1797G>C p.V599= | Silent (SNP) | VAF 33/58 reads (57%) | catalogued as COSV55962636, COSV99903675; called by muse, mutect2, varscan2
- DNAJC11 | c.1299G>A p.Q433= | Silent (SNP) | VAF 30/56 reads (54%) | catalogued as rs201664213, COSV99275465; called by muse, mutect2, varscan2
- EFCAB14 | c.294C>G p.L98= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV100905551; called by muse, mutect2, varscan2
- EPS8L3 | c.1407G>A p.L469= (on ENST00000361965 / NM_133181.4; = p.L439= on NM_024526.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/143 reads (31%) | catalogued as COSV100719670, COSV62609474; called by muse, mutect2, varscan2
- EVPL | c.2868G>A p.E956= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as rs201462599, COSV100044046; called by muse, mutect2, varscan2
- EXOC6B | c.2181C>T p.F727= | Silent (SNP) | VAF 54/90 reads (60%) | catalogued as COSV55545703, COSV99723001; called by muse, mutect2, varscan2
- FAM111A | c.1041G>T p.V347= | Silent (SNP) | VAF 35/94 reads (37%) | catalogued as COSV100659333, COSV64655126; called by muse, mutect2, varscan2
- FAM207A | c.441C>A p.L147= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV99384212, COSV99384229; called by muse, mutect2
- FER1L6 | c.3663G>A p.L1221= | Silent (SNP) | VAF 12/188 reads (6%) | catalogued as COSV101205519; called by muse, mutect2
- FGD6 | c.1158G>A p.L386= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as COSV59696544; called by muse, mutect2
- FLNA | c.6486C>T p.L2162= (on ENST00000369850 / NM_001110556.2; = p.L2154= on NM_001456.3) | Silent (SNP) | VAF 27/43 reads (63%) | catalogued as COSV100774335, COSV61052873; called by muse, mutect2, varscan2
- GLB1L2 | c.1314C>A p.T438= | Silent (SNP) | VAF 44/134 reads (33%) | catalogued as COSV100335170; called by muse, mutect2, varscan2
- GLOD4 | c.19C>T p.L7= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV100022448; called by muse, mutect2, varscan2
- GRIN2B | c.69C>G p.G23= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV101662934; called by muse, mutect2, varscan2
- GUSB | c.1254C>T p.F418= | Silent (SNP) | VAF 39/88 reads (44%) | catalogued as COSV100512513; called by muse, mutect2, varscan2
- IFT172 | c.9G>A p.L3= | Silent (SNP) | VAF 29/44 reads (66%) | catalogued as rs1341877669, COSV99253806; called by muse, mutect2, varscan2
- IL10 | c.495C>T p.I165= | Silent (SNP) | VAF 37/73 reads (51%) | catalogued as COSV100894730; called by muse, mutect2, varscan2
- ITM2C | c.708G>A p.R236= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as COSV100419561; called by muse, mutect2, varscan2
- ITPR3 | c.7509C>T p.I2503= | Silent (SNP) | VAF 37/76 reads (49%) | catalogued as rs767020507, COSV100951969; called by muse, mutect2, varscan2
- KCNK15 | c.195G>A p.L65= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100865776; called by muse, mutect2
- KIAA0319L | c.1566C>T p.L522= | Silent (SNP) | VAF 121/300 reads (40%) | catalogued as COSV100356945; called by muse, mutect2, varscan2
- KRT17 | c.147C>T p.G49= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV100245062; called by muse, mutect2, varscan2
- LEPR | c.657A>C p.G219= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100756340; called by muse, mutect2, varscan2
- LHX4 | c.9G>A p.Q3= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV55373073, COSV99761212; called by muse, mutect2, varscan2
- LMAN2L | c.414G>C p.R138= | Silent (SNP) | VAF 60/116 reads (52%) | catalogued as COSV99383140; called by muse, mutect2, varscan2
- LRFN3 | c.832C>T p.L278= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99873200; called by muse, mutect2, varscan2
- LRP1 | c.4779C>T p.I1593= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV99674491; called by muse, mutect2, varscan2
- LRRC55 | c.531C>T p.L177= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as COSV101546707; called by muse, mutect2, varscan2
- LRRIQ4 | c.798G>C p.G266= | Silent (SNP) | VAF 27/47 reads (57%) | catalogued as COSV100540116, COSV61619895; called by muse, mutect2, varscan2
- MAGOH | c.402C>T p.F134= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs370758699, COSV101012333; called by muse, mutect2, varscan2
- MECP2 | c.471C>T p.F157= | Silent (SNP) | VAF 58/71 reads (82%) | catalogued as CM003455, CM078121, COSV100317877; called by muse, mutect2, varscan2
- MMP24 | c.1800G>A p.V600= | Silent (SNP) | VAF 43/109 reads (39%) | catalogued as COSV99863674; called by muse, mutect2, varscan2
- MYH9 | c.4854C>T p.D1618= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as COSV99337988; called by muse, mutect2
- MYRF | c.1416G>A p.T472= (on ENST00000278836 / NM_001127392.3; = p.T463= on NM_013279.4) | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs371686409, COSV53890811, COSV53891681; called by muse, mutect2, varscan2
- NDN | c.24G>C p.L8= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV100086230, COSV100086254; called by muse, mutect2
- NEB | c.7071C>T p.F2357= | Silent (SNP) | VAF 148/270 reads (55%) | catalogued as COSV50806544, COSV99415907; called by muse, mutect2, varscan2
- NPC1L1 | c.3831C>T p.G1277= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs771829023, COSV99202749; called by muse, mutect2, varscan2
- NPR3 | c.277C>T p.L93= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV99422379, COSV99423754; called by muse, mutect2, varscan2
- NT5C | c.183G>A p.V61= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs1197180511, COSV99822579; called by muse, mutect2
- NYNRIN | c.5244C>T p.F1748= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV101230515; called by muse, mutect2, varscan2
- OBSCN | c.201C>G p.L67= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99473822; called by muse, mutect2
- OR11A1 | c.453C>G p.L151= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV101010682; called by muse, mutect2, varscan2
- OR5B17 | c.93C>T p.L31= | Silent (SNP) | VAF 65/163 reads (40%) | catalogued as rs1032402689, COSV100641853; called by muse, mutect2, varscan2
- OR5D14 | c.426C>T p.L142= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as COSV100162184; called by muse, mutect2, varscan2
- OR8D1 | c.189C>T p.L63= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as rs766090396, COSV63442715; called by muse, mutect2, varscan2
- OR8S1 | c.351G>T p.G117= | Silent (SNP) | VAF 42/111 reads (38%) | catalogued as COSV100043471, COSV100043555; called by muse, varscan2
- PCDHA5 | c.141C>T p.I47= | Silent (SNP) | VAF 52/116 reads (45%) | catalogued as COSV65351442; called by muse, varscan2
- PCDHA5 | c.220C>T p.L74= | Silent (SNP) | VAF 74/218 reads (34%) | catalogued as COSV100972140; called by muse, varscan2
- PCDHA6 | c.1824G>A p.S608= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs782789312, COSV100971175, COSV65343226, COSV65345214; called by muse, mutect2, varscan2
- PEX11B | c.588C>A p.L196= | Silent (SNP) | VAF 41/255 reads (16%) | catalogued as COSV100994749, COSV65199448; called by muse, mutect2, varscan2
- PFKFB3 | c.846G>C p.L282= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV100431769; called by muse, mutect2, varscan2
- PHLPP1 | c.3948G>A p.L1316= | Silent (SNP) | VAF 57/158 reads (36%) | catalogued as COSV99407495; called by muse, mutect2, varscan2
- PIWIL3 | c.903A>C p.T301= | Silent (SNP) | VAF 39/120 reads (33%) | catalogued as COSV100177375; called by muse, mutect2, varscan2
- POLE2 | c.1374C>G p.V458= | Silent (SNP) | VAF 47/69 reads (68%) | catalogued as COSV53561107, COSV99364607; called by muse, mutect2, varscan2
- POLR1A | c.2430C>G p.V810= | Silent (SNP) | VAF 49/82 reads (60%) | catalogued as rs1446185326, COSV99807184; called by muse, mutect2, varscan2
- PPP1R13B | c.2331C>T p.P777= | Silent (SNP) | VAF 55/91 reads (60%) | catalogued as COSV99157705; called by muse, mutect2, varscan2
- PPP3CB | c.681C>T p.F227= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV100646041, COSV100646054; called by muse, mutect2, varscan2
- RAP2A | c.72G>C p.V24= | Silent (SNP) | VAF 39/59 reads (66%) | catalogued as COSV99807193; called by muse, mutect2, varscan2
- REXO1 | c.735C>T p.L245= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as rs941974842, COSV99402052; called by muse, mutect2, varscan2
- RGL3 | c.708C>T p.L236= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV100805282; called by muse, mutect2, varscan2
- RHOBTB3 | c.624G>A p.K208= | Silent (SNP) | VAF 49/155 reads (32%) | catalogued as COSV101183148; called by muse, mutect2, varscan2
- S1PR1 | c.156C>T p.F52= | Silent (SNP) | VAF 51/143 reads (36%) | catalogued as COSV100541488, COSV59512441; called by muse, mutect2, varscan2
- SDK1 | c.5397G>A p.Q1799= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs1326261519, COSV101268839, COSV67381206; called by muse, mutect2, varscan2
- SHMT2 | c.693C>G p.L231= | Silent (SNP) | VAF 50/148 reads (34%) | catalogued as COSV100197005, COSV61074111; called by muse, mutect2, varscan2
- SLC12A4 | c.1128C>G p.L376= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100311334; called by muse, mutect2
- SLC35F4 | c.729G>T p.L243= (on ENST00000339762 / NM_001352015.2; = p.L207= on NM_001206920.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV100333586; called by muse, mutect2
- SLC4A1 | c.339C>G p.V113= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV52263975, COSV99293040; called by muse, mutect2, varscan2
- SLC9C2 | c.879G>A p.P293= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs749628917, COSV62945519; called by muse, mutect2, varscan2
- STAU1 | c.1587G>C p.L529= (on ENST00000371856 / NM_001319135.1; = p.L448= on NM_004602.3) | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as rs770244577, COSV100574285; called by muse, mutect2, varscan2
- SUPT5H | c.1797C>T p.I599= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as rs780810398, COSV100781931; called by muse, mutect2, varscan2
- SUSD4 | c.615G>A p.V205= | Silent (SNP) | VAF 52/185 reads (28%) | catalogued as COSV100663530; called by muse, mutect2, varscan2
- SYDE1 | c.1902G>A p.V634= | Silent (SNP) | VAF 47/151 reads (31%) | catalogued as rs925404148, COSV99654608; called by muse, mutect2, varscan2
- SYNE1 | c.15825C>G p.T5275= (on ENST00000367255 / NM_182961.4; = p.T5204= on NM_033071.3) | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV99552128, COSV99555131; called by muse, mutect2, varscan2
- TALDO1 | c.54C>G p.L18= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100032477; called by muse, mutect2, varscan2
- TIAM1 | c.4659C>G p.L1553= | Silent (SNP) | VAF 37/77 reads (48%) | catalogued as COSV99733154; called by muse, mutect2, varscan2
- TIAM1 | c.3711C>T p.I1237= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as COSV99733157; called by muse, mutect2, varscan2
- TMEM145 | c.1344C>T p.I448= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as COSV99234701; called by muse, mutect2, varscan2
- TNR | c.1461G>C p.L487= | Silent (SNP) | VAF 34/112 reads (30%) | catalogued as COSV99687965; called by muse, mutect2, varscan2
- TRANK1 | c.5079C>T p.F1693= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs759542279, COSV57147721; called by muse, mutect2, varscan2
- TRPV4 | c.462C>G p.L154= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as COSV99924432; called by muse, varscan2
- TULP2 | c.726G>T p.L242= | Silent (SNP) | VAF 39/82 reads (48%) | catalogued as COSV99667691; called by muse, mutect2, varscan2
- UBE3B | c.1587G>A p.L529= | Silent (SNP) | VAF 65/154 reads (42%) | catalogued as COSV99783693; called by muse, mutect2, varscan2
- VPS4B | c.903G>A p.P301= | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as rs767179993, COSV99447709; called by muse, mutect2
- VPS53 | c.1596C>T p.L532= (on ENST00000571805 / NM_001366253.2; = p.L503= on NM_018289.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV99345462; called by muse, mutect2
- VRK3 | c.540C>G p.L180= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as COSV100371382; called by muse, mutect2, varscan2
- ZC3H4 | c.357G>A p.K119= | Silent (SNP) | VAF 147/465 reads (32%) | catalogued as COSV99451794; called by muse, varscan2
- ZMYND11 | c.1323G>A p.K441= | Silent (SNP) | VAF 48/115 reads (42%) | catalogued as COSV100555808, COSV100555909; called by muse, mutect2, varscan2
- ZNF658 | c.2523C>G p.L841= | Silent (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73701171 G>C | 3'Flank (SNP) | VAF 42/58 reads (72%) | catalogued as rs1257948678; called by muse, mutect2, varscan2
- DNAH14 | c.1032+98G>C | Intron (SNP) | VAF 23/101 reads (23%) | catalogued as COSV100835846; called by muse, mutect2, varscan2
- FAM153CP | chr5:178055978 G>A | 3'Flank (SNP) | VAF 47/123 reads (38%) | called by muse, mutect2, varscan2
- HNF4A | c.115+1096G>C | Intron (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- OR2W5 | n.946C>T | RNA (SNP) | VAF 10/174 reads (6%) | called by muse, mutect2
- VSTM4 | c.457+3843G>C | Intron (SNP) | VAF 29/98 reads (30%) | catalogued as COSV100039155; called by muse, mutect2, varscan2
- WT1 | chr11:32438956 G>C | 5'Flank (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2
- ZNF658B | n.1399C>T | RNA (SNP) | VAF 60/191 reads (31%) | called by muse, mutect2, varscan2
